Somatic mutation profile of tumor specimen TCGA-KN-8426-01A (aliquot TCGA-KN-8426-01A-11D-2310-10) from TCGA case TCGA-KN-8426, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 50.2 years (18,345 days).
Specimen TCGA-KN-8426-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d2d9032-1599-417c-9a87-a3733c16079c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8426-11A (Solid Tissue Normal), aliquot TCGA-KN-8426-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a5168c3-e7e0-4ffa-809b-992e0c62d345

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, 3'UTR 3, Nonsense Mutation 3, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS6 | c.3031C>T p.R1011C | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs769190743, COSV58683484; called by muse, mutect2, varscan2
- ARAP1 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.537); catalogued as rs752586340, COSV100501807; called by mutect2, varscan2
- CBR4 | c.105C>A p.N35K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.355); catalogued as rs1231680619, COSV100085795; called by muse, mutect2
- GALNS | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1202367465; called by muse, mutect2, varscan2
- MYH9 | c.2573G>A p.R858K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53381788; called by muse, mutect2, varscan2
- PCDHA11 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs987284077, COSV56494066; called by muse, mutect2, varscan2
- PNRC1 | c.871A>G p.S291G | Missense Mutation (SNP) | VAF 66/92 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60140304; called by muse, mutect2, varscan2
- RTL9 | c.3139G>T p.A1047S | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs748150672; called by muse, mutect2, varscan2
- SPOCK3 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 23/746 reads (3%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.043); catalogued as COSV62723362; called by muse, mutect2
- SPTBN4 | c.707A>G p.N236S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs774529480; called by muse, mutect2, varscan2
- SYT16 | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV101413569; called by muse, mutect2
- TCOF1 | c.3680C>G p.S1227C (on ENST00000377797 / NM_001135243.1; = p.S1150C on NM_000356.4) | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.711); catalogued as COSV60349980; called by muse, mutect2, varscan2
- TRIP11 | c.2426T>G p.L809R | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV99971178; called by muse, mutect2, varscan2
- ZNF155 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99525607; called by muse, mutect2
- CCDC59 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 15/278 reads (5%) | called by muse, mutect2
- CCDC73 | c.1601C>A p.P534Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CLEC6A | c.227G>A p.W76* | Nonsense Mutation (SNP) | VAF 75/162 reads (46%) | called by muse, mutect2, varscan2
- DNAH3 | c.4873G>T p.E1625* | Nonsense Mutation (SNP) | VAF 61/161 reads (38%) | called by muse, mutect2, varscan2
- DNAJB7 | c.286G>T p.V96F | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- FLNA | c.3449T>A p.F1150Y | Missense Mutation (SNP) | VAF 93/114 reads (82%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GFM1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- GJC1 | c.1168G>T p.G390W | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGSF10 | c.4895C>A p.S1632Y | Missense Mutation (SNP) | VAF 118/156 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ITGB1 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 76/99 reads (77%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAIR1 | c.36G>A p.V12= | Splice Region (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- SHC1 | c.1006G>T p.A336S (on ENST00000368445 / NM_183001.5; = p.A226S on NM_003029.5) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SLC35D1 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- AGGF1 | c.73C>T p.L25= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs904418498; called by muse, varscan2
- CEACAM5 | c.1971C>G p.V657= | Silent (SNP) | VAF 55/215 reads (26%) | catalogued as rs149056934; called by muse, mutect2, varscan2
- MUC16 | c.43188G>A p.S14396= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs762197996, COSV66690291; called by muse, mutect2, varscan2
- PAQR8 | c.279C>T p.F93= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- SVIL | c.5778C>T p.H1926= (on ENST00000355867 / NM_021738.3; = p.H1500= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs201300228; called by muse, mutect2, varscan2
- HRH1 | c.*2984G>A | 3'UTR (SNP) | VAF 25/32 reads (78%) | catalogued as rs1306690997; called by muse, varscan2
- IGHV3-23 | c.-6C>T | 5'UTR (SNP) | VAF 51/228 reads (22%) | catalogued as rs376340937; called by muse, mutect2, varscan2
- PABPC3 | c.*256G>A | 3'UTR (SNP) | VAF 10/61 reads (16%) | catalogued as rs1256976283, COSV99879388; called by muse, mutect2, varscan2
- SOCS4 | c.*3920C>T | 3'UTR (SNP) | VAF 27/212 reads (13%) | catalogued as COSV100216119; called by muse, mutect2, varscan2
